Somatic mutation profile of tumor specimen TCGA-AO-A1KS-01A (aliquot TCGA-AO-A1KS-01A-11D-A13L-09) from TCGA case TCGA-AO-A1KS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.1 years (25,230 days).
Specimen TCGA-AO-A1KS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7862b2ac-a6a1-450f-9a89-dfc2f7fe19da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A1KS-10A (Blood Derived Normal), aliquot TCGA-AO-A1KS-10A-01W-A14R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e70d932-4c26-4de7-b8a6-1c26e21d823e

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 24, Silent 14, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC7 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs771659945, COSV71444043; called by muse, mutect2
- ANKRD11 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV56370653; called by muse, mutect2, varscan2
- B3GLCT | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 149/233 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58458334; called by muse, varscan2
- CLK1 | c.310T>G p.S104A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV58435697; called by muse, mutect2, varscan2
- COL6A6 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567427258, COSV62021514; called by muse, mutect2, varscan2
- CRTC3 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs367566158; called by muse, mutect2
- EVC2 | c.518del p.L173Rfs*105 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | catalogued as COSV100186744, COSV60401627; called by mutect2, pindel, varscan2
- FGB | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV57417597; called by muse, mutect2, varscan2
- GBX2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1467112182, COSV60445806; called by muse, mutect2, varscan2
- ISLR2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs1470932883, COSV62303620; called by muse, mutect2, varscan2
- ITGAD | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs144853512; called by muse, mutect2, varscan2
- KMT5B | c.577A>T p.S193C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV58569452; called by muse, mutect2, varscan2
- KNTC1 | c.3999+4_3999+7del p.X1333_splice | Splice Site (DEL) | VAF 16/76 reads (21%) | catalogued as rs1378770139; called by pindel, varscan2
- LRRIQ1 | c.3443C>T p.S1148L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1393488672, COSV67837624; called by muse, mutect2, varscan2
- MTRR | c.571A>C p.S191R (on ENST00000264668; = p.S164R on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as rs779803224, COSV52946599; called by muse, mutect2, varscan2
- MYOCD | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as rs778569527, COSV58506450; called by muse, mutect2, varscan2
- NSD3 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.389); catalogued as rs200818177, COSV57668153; called by muse, mutect2, varscan2
- PBX2 | c.1113+1G>A p.X371_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100904028; called by muse, mutect2, varscan2
- PCLO | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV61662563; called by muse, varscan2
- PLA2G4A | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997191590, COSV66556609; called by muse, mutect2, varscan2
- PLEKHG2 | c.184G>C p.G62R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52689383; called by muse, mutect2, varscan2
- PTGIS | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs767832954, COSV54837117, COSV54840735; called by muse, mutect2
- RBBP7 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as COSV100417878, COSV100417927, COSV58113394; called by muse, mutect2, varscan2
- SEC63 | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64601865; called by muse, mutect2, varscan2
- SYCE1 | c.119T>G p.V40G (on ENST00000343131 / NM_001143764.3; = p.V4G on NM_130784.3) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV58219296; called by muse, mutect2, varscan2
- TDRD10 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs543994368, COSV63813622, COSV99055208; called by muse, mutect2, varscan2
- TIPRL | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV63208119; called by muse, varscan2
- TNMD | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as rs1340628341, COSV65977740; called by muse, mutect2, varscan2
- TRPV2 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs373733043; called by muse, mutect2
- PSMD10 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- APOB | c.11952C>A p.T3984= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1447813723, COSV51941498; called by muse, mutect2
- ARHGAP11A | c.69G>A p.V23= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV64381595; called by muse, mutect2, varscan2
- CD69 | c.306G>A p.V102= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV57303665; called by muse, mutect2, varscan2
- CSN2 | c.433C>T p.L145= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV61991929, COSV61992652; called by muse, mutect2, varscan2
- CYYR1 | c.348C>T p.Y116= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs766711396, COSV54837309; called by muse, mutect2, varscan2
- FLT1 | c.1701G>A p.P567= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs769362764, COSV99163828; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGHMBP2 | c.633C>T p.I211= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV54825996; called by muse, mutect2, varscan2
- MX2 | c.1167A>G p.L389= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV58099199; called by muse, mutect2, varscan2
- PTPN9 | c.381A>G p.V127= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV60724029; called by muse, mutect2, varscan2
- SEMA6A | c.2736C>T p.Y912= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs376332713; called by muse, mutect2, varscan2
- SLC10A5 | c.1077G>A p.T359= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs143046260, COSV72828476; called by muse, mutect2, varscan2
- TDRKH | c.717C>T p.N239= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs763419568, COSV64316696; called by muse, mutect2, varscan2
- UBE2O | c.549C>T p.I183= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60067318; called by muse, mutect2, varscan2
- WDR44 | c.2445C>G p.T815= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV54168377; called by muse, mutect2, varscan2
